Somatic mutation profile of tumor specimen 1105237 (aliquot 7316UP-662-1105237) from CPTAC case C204057, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105237: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73e57051-8646-4d89-814a-f3e7c651a680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105284 (Blood Derived Normal), aliquot 7316UP-302-1105284; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ffed74-1e87-4898-b51e-a7469d13db44

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.1945G>C p.A649P | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as CD1515401; called by muse, mutect2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2
- CBLL2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100081584; called by muse, mutect2
- PPP1R3F | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs782455380; called by muse, mutect2
- PITPNM1 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHB15 | c.1893C>T p.S631= | Silent (SNP) | VAF 25/767 reads (3%) | called by muse, mutect2
